Gene-level copy-number profile of tumor specimen TCGA-02-0071-01A from TCGA case TCGA-02-0071, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.2 years (19,425 days).
Specimen TCGA-02-0071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a7f5fece-41a9-4b78-a874-a05cae0e7c40.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0071-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c84638b3-227c-4e12-90c7-f05cdd2a743c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 2: 4,878; copy number 3: 1,448; copy number 4: 48,167; copy number 5: 22; copy number 6: 5,047; copy number 7: 80; copy number 16: 78; copy number 54: 11; copy number 57: 1; copy number 58: 4; copy number 75: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0071-01): tumor purity 0.7, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–27,944,497, 66 genes (broad region; genes not listed).
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 106 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,724,495–203,273,641, 25 genes, copy number 16 (within-gene range 4–16): KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A, PPFIA4, MYOG, ADORA1, AC105940.2, AC105940.1, MYBPH, CHI3L1, CHIT1.
- chr1:203,400,266–205,211,702, 53 genes, copy number 16 (within-gene range 4–16): LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK.
- chr7:47,963,288–48,108,736, 4 genes, copy number 58: HUS1, SUN3, C7orf57, UPP1.
- chr7:54,542,325–55,211,628, 12 genes, copy number 75: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr12:43,793,723–43,806,328, 1 gene, copy number 57: TWF1.
- chr12:46,183,063–46,270,017, 1 gene, copy number 54 (within-gene range 3–54): SLC38A1.
- chr12:68,746,125–68,971,570, 10 genes, copy number 54 (within-gene range 3–54): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
